Somatic mutation profile of tumor specimen C3L-01049-01 (aliquot CPT0217430011) from CPTAC case C3L-01049, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 46.6 years (17,038 days).
Specimen C3L-01049-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 142bfa15-e8c6-43ec-bd85-873a06623585.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01049-31 (Blood Derived Normal), aliquot CPT0220120002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1f9a163-c670-4062-ba6e-d13991246c31

The open-access MAF lists 56 somatic variants for this specimen: 38 protein-altering or splice-affecting, 12 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 12, Nonsense Mutation 4, RNA 3, Intron 2, 5'Flank 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.273G>A p.W91* | Nonsense Mutation (SNP) | VAF 183/257 reads (71%) | hotspot (GDC flag); catalogued as rs876660548, CM065495, COSV52673580; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A4GALT | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 194/716 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as rs754275300; called by muse, mutect2, varscan2
- ALPK2 | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 66/196 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV64492751, COSV64494034; called by muse, mutect2, varscan2
- ANO5 | c.268G>A p.V90I | Missense Mutation (SNP) | VAF 54/211 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1200514344; called by muse, mutect2, varscan2
- ART1 | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 39/109 reads (36%) | catalogued as rs764813601; called by muse, mutect2, varscan2
- CCER1 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 75/191 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs772988715; called by muse, mutect2, varscan2
- DEFB125 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs757216800, COSV66703620; called by muse, mutect2, varscan2
- FAM47C | c.1841G>A p.R614H | Missense Mutation (SNP) | VAF 216/294 reads (73%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.934); catalogued as rs782535331, COSV63723697; called by muse, mutect2, varscan2
- HRNR | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 228/426 reads (54%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs374023812; called by muse, mutect2, varscan2
- IL18RAP | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 41/133 reads (31%) | catalogued as rs770129762, COSV51828680; called by muse, mutect2, varscan2
- IL37 | c.470A>G p.Y157C | Missense Mutation (SNP) | VAF 73/187 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as rs1349350766; called by muse, mutect2, varscan2
- LRRC9 | c.4295T>C p.F1432S (on ENST00000445360; = p.F1488= on NM_001355272.2) | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs778743283; called by muse, mutect2
- PIK3CA | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.242); catalogued as rs201269904, COSV55904566; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PKHD1 | c.11215C>T p.R3739W | Missense Mutation (SNP) | VAF 52/271 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs369626373; called by muse, mutect2, varscan2
- POM121L2 | c.1189C>G p.L397V | Missense Mutation (SNP) | VAF 106/363 reads (29%) | SIFT tolerated (0.94); PolyPhen benign (0.116); catalogued as COSV66276059; called by muse, mutect2, varscan2
- RBAK | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 55/157 reads (35%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.981); catalogued as rs373122199; called by muse, mutect2, varscan2
- SUN1 | c.2207C>T p.T736M (on ENST00000405266 / NM_001367651.1; = p.T616M on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/377 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs542993409, COSV67451925; called by muse, mutect2, varscan2
- VSIG4 | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 75/96 reads (78%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.682); catalogued as rs766175105; called by muse, mutect2, varscan2
- ZDBF2 | c.6785C>T p.A2262V | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs552788507, COSV65626663; called by muse, mutect2, varscan2
- ZNF727 | c.404A>C p.Q135P | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV101407146; called by muse, mutect2, varscan2
- ZNF831 | c.1849C>T p.Q617* | Nonsense Mutation (SNP) | VAF 20/71 reads (28%) | catalogued as COSV64042506; called by muse, mutect2, varscan2
- ANO1 | c.1747T>C p.Y583H | Missense Mutation (SNP) | VAF 85/270 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DOCK6 | c.1432G>T p.D478Y | Missense Mutation (SNP) | VAF 32/266 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- EMC2 | c.821G>A p.S274N | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ERCC6 | c.3983+2T>C p.X1328_splice | Splice Site (SNP) | VAF 17/420 reads (4%) | called by muse, mutect2
- GALNT7 | c.290A>G p.H97R | Missense Mutation (SNP) | VAF 98/321 reads (31%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMT2D | c.3731T>G p.V1244G | Missense Mutation (SNP) | VAF 69/144 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- MMP25 | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 103/272 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- MS4A14 | c.1717G>C p.G573R | Missense Mutation (SNP) | VAF 57/329 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- MS4A4E | c.81A>G p.I27M | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NLRX1 | c.1855G>T p.V619F | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- OR2T4 | c.593T>A p.F198Y | Missense Mutation (SNP) | VAF 209/427 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- P2RY13 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT tolerated (0.95); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PABPC4L | c.171C>A p.N57K | Missense Mutation (SNP) | VAF 162/471 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTEN | c.230del p.D77Afs*22 | Frame Shift Del (DEL) | VAF 82/154 reads (53%) | called by mutect2, pindel, varscan2
- PTPRT | c.1299G>C p.Q433H | Missense Mutation (SNP) | VAF 199/735 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- TRPC7 | c.167T>C p.I56T | Missense Mutation (SNP) | VAF 79/161 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- TYR | c.398A>T p.K133I | Missense Mutation (SNP) | VAF 98/369 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); called by mutect2, varscan2
- AQP9 | c.345G>T p.V115= | Silent (SNP) | VAF 64/231 reads (28%) | called by muse, mutect2, varscan2
- C3 | c.144C>T p.D48= | Silent (SNP) | VAF 117/340 reads (34%) | catalogued as rs372872350; called by muse, mutect2, varscan2
- CRISPLD2 | c.1095C>T p.H365= | Silent (SNP) | VAF 49/142 reads (35%) | catalogued as rs200215115; called by muse, mutect2, varscan2
- EGFL7 | c.516C>T p.D172= | Silent (SNP) | VAF 56/133 reads (42%) | catalogued as rs374085521; called by muse, mutect2, varscan2
- EPB41L3 | c.2727C>T p.V909= | Silent (SNP) | VAF 102/317 reads (32%) | catalogued as rs550438645, COSV59452829; called by muse, mutect2, varscan2
- ERN1 | c.2538C>T p.S846= | Silent (SNP) | VAF 23/214 reads (11%) | catalogued as rs751720267, COSV101458571; called by muse, mutect2, varscan2
- KCNA3 | c.1020T>C p.F340= | Silent (SNP) | VAF 260/410 reads (63%) | called by muse, mutect2, varscan2
- MAP3K15 | c.3378C>T p.A1126= | Silent (SNP) | VAF 79/95 reads (83%) | catalogued as rs143117337, COSV58833916; called by muse, mutect2, varscan2
- MXRA5 | c.5802C>T p.H1934= | Silent (SNP) | VAF 144/170 reads (85%) | catalogued as rs757827523, COSV54243410; called by muse, mutect2, varscan2
- OR5D16 | c.474C>A p.S158= | Silent (SNP) | VAF 50/141 reads (35%) | catalogued as rs373010143; called by muse, mutect2, varscan2
- OSMR | c.1515C>T p.C505= | Silent (SNP) | VAF 62/167 reads (37%) | catalogued as rs367714483; called by muse, mutect2, varscan2
- TRPM5 | c.1977C>T p.L659= | Silent (SNP) | VAF 65/193 reads (34%) | catalogued as rs370419238; called by muse, mutect2, varscan2
- ANXA2P2 | n.502C>T | RNA (SNP) | VAF 127/379 reads (34%) | catalogued as rs1416949815; called by muse, mutect2, varscan2
- DMXL1 | c.7863+3396A>T | Intron (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2
- NBPF22P | n.771G>T | RNA (SNP) | VAF 110/288 reads (38%) | called by muse, mutect2, varscan2
- OR2W5 | n.1129C>G | RNA (SNP) | VAF 64/333 reads (19%) | called by muse, mutect2, varscan2
- SCRN1 | chr7:29990229 G>A | 5'Flank (SNP) | VAF 26/506 reads (5%) | called by muse, mutect2
- TRIM4 | c.919+1095G>A | Intron (SNP) | VAF 42/148 reads (28%) | catalogued as rs771789934, COSV62470746; called by muse, mutect2, varscan2
